FM case AD15506 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/7b6dbfaf-91a0-4866-a0da-5d610331e744

Female, 70.2 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 52% (pathologist estimate recorded by GDC). Sample type: Tumor.
